Somatic mutation profile of tumor specimen 0DNWL1 from CCDI case PBCBRA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 7.2 years (2,637 days).
Specimen 0DNWL1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f177e06-648e-4a54-bea0-ef4358245e16.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNWJF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d12dce4f-cb89-45ac-8217-bb2c558742d4

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Intron 2, Nonsense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATAD1 | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 44/492 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.374); catalogued as rs189457596; called by muse, mutect2
- ATG9B | c.2392G>A p.A798T | Missense Mutation (SNP) | VAF 44/772 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.604); catalogued as rs539505941; called by muse, mutect2
- CEP170 | c.2755G>T p.D919Y | Missense Mutation (SNP) | VAF 83/351 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV60514330; called by muse, mutect2, varscan2
- CRYBB3 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 44/440 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as rs145423394; called by muse, mutect2, varscan2
- DHX38 | c.3124C>T p.R1042W | Missense Mutation (SNP) | VAF 104/248 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1353239879; called by muse, mutect2, varscan2
- DNMBP | c.22C>T p.R8* | Nonsense Mutation (SNP) | VAF 185/552 reads (34%) | catalogued as rs755674215, COSV60625548; called by muse, mutect2, varscan2
- FOXF1 | c.1081G>A p.G361R | Missense Mutation (SNP) | VAF 26/406 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); catalogued as rs886052377, COSV52287150; ClinVar: uncertain significance; called by muse, mutect2
- BCL2 | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- LAMA3 | c.4978T>A p.Y1660N | Missense Mutation (SNP) | VAF 73/441 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- SPDYE3 | c.1321C>G p.Q441E | Missense Mutation (SNP) | VAF 16/684 reads (2%) | SIFT deleterious (0.02); PolyPhen benign (0.285); called by muse, mutect2
- ZNF557 | c.104T>A p.L35* (on ENST00000414706 / NM_001044388.2; = p.L42* on NM_024341.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 46/158 reads (29%) | called by mutect2, varscan2
- NANP | c.144C>A p.I48= | Silent (SNP) | VAF 103/692 reads (15%) | called by muse, mutect2, varscan2
- ARHGEF12 | c.2226-98A>C | Intron (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- PHF1 | c.1050-61A>C | Intron (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2, varscan2
